Somatic mutation profile of tumor specimen 0DLA1Z from CCDI case PBBZBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (641 days).
Specimen 0DLA1Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9adbdf51-de03-45f9-ad73-c4ec967d2ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLA11 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da4849b0-cde0-4d53-a76d-7186363ee62d

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBBP6 | c.4381G>A p.A1461T | Missense Mutation (SNP) | VAF 18/634 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1410705984; called by muse, mutect2
- ANGPTL3 | c.1065A>T p.E355D | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MMP11 | c.212_243del p.P71Rfs*6 | Frame Shift Del (DEL) | VAF 121/148 reads (82%) | called by mutect2, pindel, varscan2
- C1orf159 | c.333C>T p.N111= (on ENST00000379339 / NM_001330306.2; = p.N75= on NM_017891.5) | Silent (SNP) | VAF 96/240 reads (40%) | catalogued as rs1029236529; called by muse, mutect2, varscan2
